Gene-level copy-number profile of tumor specimen MP2PRT-PATZIX-TMP1-A from MP2PRT case MP2PRT-PATZIX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,734 days).
Specimen MP2PRT-PATZIX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 155fcd7a-2043-4ce2-a906-f99761138eda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATZIX-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/2a202e91-292b-415b-88a3-8574c9de5cfe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 18; copy number 2: 583; copy number 3: 1,081; copy number 4: 43,213; copy number 5: 5,401; copy number 6: 112; copy number 7: 7,474; copy number 8: 136; copy number 9: 232; copy number 10: 655.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 887 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 10: RPL23AP88.
- chr4:69,280,475–69,358,177, 3 genes, copy number 10: UGT2B28, AC114786.3, AC114786.2.
- chr4:69,408,828–69,423,164, 1 gene, copy number 10 (within-gene range 7–10): UGT2B24P.
- chr21:15,928,296–16,645,467, 1 gene, copy number 10 (within-gene range 8–10): MIR99AHG.
- chr21:16,284,696–46,691,226, 649 genes, copy number 10 (broad region; genes not listed).
- chr22:16,572,027–21,070,097, 232 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
